Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4616, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4616-01A (Primary Tumor).

OMENTUM, RIGHT HEMICOLECTOMY
DIFFERENTIATED ADENOCARCINOMA OF THE CECUM (6.5 CM)
INVADING THROUGH THE MUSCULARIS PROPRIA INTO PERICECAL FAT WITH MULTIPLE ISOLATED
TUMOR NODULES. NO DEFINITIVE SEROSAL INVASION IS IDENTIFIED.
TUMORS PRESENT AT THE RADIAL PERICECAL SOFT TISSUE MARGIN AND INTRAVASCULAR TUMOR IS
PRESENT AT THE PROXIMAL MESENTERIC MARGIN (see comment).
EXTENSIVE ANGIOLYMPHATIC, VASCULAR, AND PERINEURAL INVASION.
ISOLATED FOCI OF METASTATIC ADENOCARCINOMA ARE PRESENT ON THE SURFACE OF THE OMENTUM
AND WITHIN THE MUSCULARIS PROPRIA OF THE TERMINAL ILEUM.
PROXIMAL ILEUM AND DISTAL COLON MARGINS OF RESECTION ARE FREE OF CARCINOMA.
METASTATIC ADENOCARCINOMA IN THIRTEEN OF TWENTY-THREE LYMPH NODES (13/23).
SEPARATE TUBULAR ADENOMA.
PATHOLOGIC STAGE: pT3c/d N2 M1.
APPENDIX NOT IDENTIFIED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS

SPECIMEN TYPE: Right hemicolectomy
SPECIMEN LENGTH: 40 cm
TUMOR SITE: Cecum
TUMOR CONFIGURATION: Infiltrative
TUMOR SIZE: Greatest dimension: 6.5 cm
Additional dimensions: 6.0 x 5.5 cm
INTACTNESS OF MESORECTUM: Not applicable
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: High-grade (poorly differentiated to undifferentiated)
PATHOLOGIC STAGING (pTNM): pT3c/d
pN2
Number of nodes examined: 23
Number of nodes involved: 13
pM1

MARGINS:

Site(s): omentum, muscularis propria of ileum
Treatment: Untreated
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (radial) margin involved by invasive carcinoma (tumor present 0-1 mm from CRM)
Mesenteric margin involved by invasive carcinoma

ANGIOLYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Present

TUMOR BORDER CONFIGURATION:

Infiltrating

ADDITIONAL TUMOR CHARACTERISTICS:

None

ADDITIONAL PATH FINDINGS (check all that apply):

Adenoma(s)

TCGA-AZ-4616

Source: NCI Genomic Data Commons file de57c689-861b-4af5-a2a8-f3b92ba0b196 (TCGA-AZ-4616.A2E6B613-40A7-4B4B-91F9-AFFB8541D909.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).